EXCEPTIONAL_RESPONDERS case ER-B0GI — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4eb9ebd1-f934-4857-abb9-78b0e83f7d0f

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 69.2 years (25,268 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 622 days (1.7 years); Days to best overall response: 125 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 55 days; Days to treatment end: 372 days (1.0 years).

Follow-up (1 entry)
- Days to follow up: 622 days (1.7 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 622 days (1.7 years); Days to recurrence: 0 days; Days progression-free: 540 days (1.5 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0GI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GI-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 35; Percent normal cells: 35; Percent necrosis: 5; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
